Somatic mutation profile of tumor specimen TCGA-44-6774-01A (aliquot TCGA-44-6774-01A-21D-1855-08) from TCGA case TCGA-44-6774, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 56.0 years (20,462 days).
Specimen TCGA-44-6774-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fa65836-a88c-474d-b157-31cf78ef340a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-6774-10A (Blood Derived Normal), aliquot TCGA-44-6774-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80f7616d-b100-45a1-92c5-e804690ccbd6

The open-access MAF lists 315 somatic variants for this specimen: 234 protein-altering or splice-affecting, 71 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 194, Silent 71, Nonsense Mutation 29, Frame Shift Del 6, Intron 4, Splice Site 3, RNA 3, 3'Flank 2, Frame Shift Ins 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1862A>G p.N621S (on ENST00000288602 / NM_001374244.1; = p.N581S on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs121913370, COSV56058108, COSV56106422, COSV56110832; ClinVar: likely pathogenic; called by muse, mutect2
- NEFL | c.1261C>T p.R421* | Nonsense Mutation (SNP) | VAF 16/100 reads (16%) | catalogued as rs191346286, CM1411101, COSV55337228; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 39/109 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTG2 | c.1077C>A p.S359R | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.918); catalogued as COSV61828505; called by muse, mutect2, varscan2
- ADAM23 | c.2271C>A p.C757* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as COSV52217141; called by muse, mutect2, varscan2
- AIFM1 | c.1040A>T p.Y347F | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV54855134; called by muse, mutect2, varscan2
- ALDH8A1 | c.1250A>G p.Y417C | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55642118; called by muse, mutect2, varscan2
- AMER1 | c.2339G>T p.G780V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV57661597; called by muse, mutect2, varscan2
- ANKRD34A | c.547T>A p.S183T | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV60161072; called by muse, mutect2, varscan2
- ANO3 | c.2278T>C p.L760= | Splice Region (SNP) | VAF 26/123 reads (21%) | catalogued as rs763534869, COSV56793197; called by muse, mutect2, varscan2
- APOL4 | c.573C>G p.I191M (on ENST00000352371 / NM_145660.2; = p.I188M on NM_030643.4) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV60654686; called by muse, mutect2, varscan2
- ARHGEF15 | c.1609C>T p.R537W | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1165475074, COSV100730007; called by mutect2, varscan2
- ARHGEF15 | c.1720A>T p.T574S | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV62725365; called by muse, mutect2
- ARMC3 | c.218C>A p.T73N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.521); catalogued as COSV53060138, COSV53062115; called by muse, mutect2, varscan2
- ARSF | c.713C>A p.T238K | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV63839794; called by muse, mutect2
- ARSI | c.1552G>T p.G518C | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60817638; called by muse, mutect2, varscan2
- ASB11 | c.791C>A p.A264E | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs764279966, COSV60354998; called by muse, mutect2, varscan2
- ASB5 | c.608C>T p.T203I | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as rs1401037963, COSV56671192; called by muse, mutect2, varscan2
- ASTN1 | c.2073G>T p.K691N | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV56070898; called by muse, mutect2, varscan2
- ASXL3 | c.3790C>G p.L1264V | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.081); catalogued as rs770050296, COSV52467686; called by muse, mutect2, varscan2
- ATG16L1 | c.1552C>T p.R518* (on ENST00000392017 / NM_030803.7; = p.R499* on NM_017974.4) | Nonsense Mutation (SNP) | VAF 16/76 reads (21%) | catalogued as rs772134294, COSV61467096; called by muse, mutect2, varscan2
- ATP2B1 | c.768G>T p.K256N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.399); catalogued as COSV53808206; called by muse, mutect2, varscan2
- ATP5MC3 | c.403G>C p.A135P | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99507084; called by muse, mutect2, varscan2
- BIRC2 | c.1225G>T p.V409L | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV57161846; called by muse, mutect2, varscan2
- BRINP3 | c.1369C>G p.R457G | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV100818882, COSV66516744; called by muse, mutect2, varscan2
- BRPF3 | c.3367G>T p.E1123* | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | catalogued as COSV60207720; called by muse, mutect2, varscan2
- BTBD8 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as COSV61546468; called by muse, mutect2
- C5orf24 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100574463, COSV57542649; called by muse, mutect2, varscan2
- CACNA1C | c.3097G>T p.V1033L | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.984); catalogued as COSV59725271, COSV59737416; called by muse, mutect2, varscan2
- CCDC112 | c.820G>T p.A274S | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.92); catalogued as COSV65473282; called by muse, mutect2, varscan2
- CCDC40 | c.1069A>T p.S357C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53900180; called by muse, mutect2, varscan2
- CD300LB | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.648); catalogued as COSV58725811; called by muse, mutect2, varscan2
- CHI3L2 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63874122; called by muse, mutect2, varscan2
- CLEC1A | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59532389, COSV59533782; called by muse, mutect2
- CNOT3 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55363907; called by muse, mutect2, varscan2
- CNTNAP5 | c.949A>T p.K317* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV70488630; called by muse, mutect2, varscan2
- COL14A1 | c.5183G>T p.S1728I | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as COSV52856136; called by muse, mutect2, varscan2
- COL3A1 | c.1420G>T p.G474C | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58589302; called by muse, mutect2, varscan2
- COL9A1 | c.1414G>T p.G472C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57885054; called by muse, mutect2, varscan2
- CPED1 | c.2009C>A p.P670Q | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60003598; called by muse, varscan2
- CPS1 | c.3356C>T p.A1119V | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV51811956; called by muse, mutect2, varscan2
- CSMD3 | c.659C>A p.A220D | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.493); catalogued as COSV52196483; called by muse, mutect2, varscan2
- CSRNP2 | c.818T>G p.I273S | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV50397807; called by muse, mutect2, varscan2
- CXorf56 | c.529C>G p.R177G (on ENST00000536133 / NM_001170570.2; = p.R191G on NM_022101.4) | Missense Mutation (SNP) | VAF 66/319 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV100233323, COSV57438320; called by muse, mutect2, varscan2
- CYBB | c.548C>A p.T183K | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD105751, COSV66085489, COSV66086343; called by muse, mutect2, varscan2
- DENND10 | c.401T>A p.I134K | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.347); catalogued as COSV63857716; called by muse, mutect2, varscan2
- DIDO1 | c.1660G>T p.G554C | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV56624269; called by muse, mutect2, varscan2
- DLK1 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV57991790; called by muse, mutect2, varscan2
- DNAH5 | c.4436G>T p.C1479F | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.449); catalogued as rs369935072; called by muse, mutect2, varscan2
- DNAH8 | c.11087C>T p.T3696I | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV100543923, COSV59451066; called by muse, mutect2, varscan2
- DNAH9 | c.3773T>A p.L1258Q | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52352750; called by muse, mutect2, varscan2
- EGFL6 | c.597C>A p.Y199* | Nonsense Mutation (SNP) | VAF 41/181 reads (23%) | catalogued as rs1244104608, COSV63634049; called by muse, mutect2, varscan2
- ELOVL2 | c.502C>A p.Q168K | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV61155520; called by muse, mutect2, varscan2
- EVL | c.1078C>G p.P360A (on ENST00000402714 / NM_001330221.2; = p.P362A on NM_016337.3) | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV67375598; called by muse, mutect2, varscan2
- EYA1 | c.148A>T p.S50C | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV58164280; called by muse, mutect2, varscan2
- EYA2 | c.215C>A p.T72K | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs373669958, COSV57944298; called by muse, mutect2, varscan2
- F5 | c.3573C>A p.S1191R | Missense Mutation (SNP) | VAF 110/440 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.312); catalogued as COSV63124709; called by muse, mutect2, varscan2
- FAM83G | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as rs1173943000, COSV58758648; called by muse, mutect2, varscan2
- FANCB | c.722A>T p.H241L | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.755); catalogued as COSV60760055; called by muse, mutect2, varscan2
- FANCM | c.2086del p.D696Tfs*8 | Frame Shift Del (DEL) | VAF 11/76 reads (14%) | catalogued as COSV57506963; called by mutect2, pindel, varscan2
- FAT4 | c.8668G>C p.G2890R | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58688468; called by muse, mutect2, varscan2
- FBN2 | c.4231G>C p.E1411Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52499675, COSV52517342, COSV99331150; called by muse, mutect2, varscan2
- FBXL13 | c.1606G>T p.D536Y | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57538866; called by muse, mutect2, varscan2
- FBXW12 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 10/85 reads (12%) | catalogued as COSV56484084; called by muse, varscan2
- FOLH1 | c.1927G>T p.A643S | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.289); catalogued as COSV57049998; called by muse, mutect2, varscan2
- FRMD7 | c.1535G>T p.R512I | Missense Mutation (SNP) | VAF 61/323 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV53746520; called by muse, mutect2, varscan2
- FSCB | c.206C>A p.T69N | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV61218286; called by muse, mutect2, varscan2
- FSTL5 | c.1663C>T p.Q555* | Nonsense Mutation (SNP) | VAF 14/98 reads (14%) | catalogued as COSV60198786; called by muse, mutect2, varscan2
- GCNA | c.916G>T p.D306Y | Missense Mutation (SNP) | VAF 47/336 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); catalogued as COSV101032742, COSV65467056; called by muse, varscan2
- GPAT2 | c.2384G>T p.S795I | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); catalogued as COSV64003531; called by muse, mutect2, varscan2
- GPHB5 | c.142C>A p.P48T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as COSV100030172; called by muse, mutect2, varscan2
- GPR18 | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.335); catalogued as rs138394107, COSV61621247; called by muse, mutect2, varscan2
- GPRC6A | c.459G>T p.M153I | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59953369; called by muse, mutect2, varscan2
- GREB1 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.285); catalogued as rs1452441565, COSV52185275; called by muse, mutect2
- GUCY2F | c.799C>G p.H267D | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.229); catalogued as COSV54303148; called by muse, mutect2, varscan2
- HAUS3 | c.1442A>G p.N481S | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs150101454; called by muse, mutect2, varscan2
- HCFC1 | c.4484G>T p.G1495V | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV60072920; called by muse, mutect2, varscan2
- HCRTR2 | c.224-1G>A p.X75_splice | Splice Site (SNP) | VAF 19/120 reads (16%) | catalogued as COSV63796168; called by muse, mutect2, varscan2
- HELLS | c.611A>G p.K204R | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV53297742; called by muse, mutect2, varscan2
- HIPK2 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.079); catalogued as COSV61228154; called by muse, mutect2, varscan2
- HKDC1 | c.1615C>T p.R539W | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370167561; called by muse, mutect2
- HNRNPUL2 | c.1088G>T p.C363F | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57132468; called by muse, mutect2, varscan2
- HOOK3 | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56883067; called by muse, mutect2, varscan2
- HTR2A | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV101096610; called by muse, mutect2, varscan2
- IGSF22 | c.39C>A p.H13Q | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV60035015; called by muse, mutect2, varscan2
- IL17B | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51002994; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1028G>T p.R343L | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); catalogued as COSV56266143, COSV56266166; called by muse, mutect2, varscan2
- INHBA | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99637312; called by muse, mutect2, varscan2
- INHBA | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.966); catalogued as COSV54221844; called by muse, mutect2
- INMT | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV50001536; called by muse, mutect2, varscan2
- IPO7 | c.704T>C p.V235A | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV65685376; called by muse, mutect2, varscan2
- IRS4 | c.1734T>A p.D578E | Missense Mutation (SNP) | VAF 68/373 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); catalogued as COSV64534082; called by muse, mutect2, varscan2
- JPH2 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100652512; called by muse, mutect2, varscan2
- JPH2 | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100652528; called by muse, mutect2, varscan2
- JUN | c.870del p.N291Tfs*23 | Frame Shift Del (DEL) | VAF 41/212 reads (19%) | catalogued as COSV100973428; called by mutect2, pindel, varscan2
- KCNH2 | c.3250C>A p.P1084T | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.57); catalogued as COSV51168098; called by muse, mutect2, varscan2
- KCNH5 | c.715A>T p.K239* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | catalogued as COSV59761972; called by muse, mutect2, varscan2
- KIAA2026 | c.5969C>G p.A1990G | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs775425300, COSV67355480; called by muse, mutect2, varscan2
- KIF15 | c.2722G>T p.A908S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV58161214; called by muse, mutect2, varscan2
- KIF16B | c.3424A>T p.S1142C | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.371); catalogued as COSV61706949; called by muse, mutect2, varscan2
- KIF5C | c.1590G>T p.Q530H | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV68481446; called by muse, mutect2, varscan2
- KIR2DL3 | c.413C>A p.T138K | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV100668136; called by muse, mutect2
- KRTAP15-1 | c.96C>G p.S32R | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as COSV61877508; called by muse, mutect2, varscan2
- LAPTM5 | c.74C>A p.A25D | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV53853421; called by muse, mutect2, varscan2
- LATS2 | c.2407G>T p.G803C | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66876272; called by muse, mutect2, varscan2
- LINS1 | c.849G>T p.M283I | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV59079328; called by muse, mutect2, varscan2
- LIPI | c.362T>A p.L121* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as COSV60712074; called by muse, mutect2, varscan2
- LMTK2 | c.2961C>G p.F987L | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV51996887; called by muse, mutect2
- LRAT | c.581G>T p.S194I | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV60477199; called by muse, mutect2
- LRFN5 | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as rs773088224, COSV53258881; called by muse, mutect2, varscan2
- LRP1B | c.12044G>A p.G4015D | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101259159, COSV67227651; called by muse, mutect2, varscan2
- LRP6 | c.2570G>T p.R857L | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53788242, COSV53788282; called by muse, mutect2, varscan2
- LRRC32 | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.069); catalogued as COSV52633272; called by muse, mutect2, varscan2
- LZTR1 | c.583G>T p.G195C | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53145247, COSV53147916; called by muse, mutect2, varscan2
- MAGEA4 | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV99367354, COSV99367364; called by muse, mutect2, varscan2
- MAGEA8 | c.243C>G p.S81R | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as COSV99674457; called by muse, mutect2, varscan2
- MAGEB18 | c.196G>T p.G66* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as COSV57464123, COSV57464174; called by muse, mutect2, varscan2
- MAGEB2 | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs45513291, COSV100975608; called by muse, mutect2, varscan2
- MAP3K19 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV59639353; called by muse, mutect2, varscan2
- MBOAT1 | c.227T>A p.V76D | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV61125299; called by muse, mutect2, varscan2
- MDN1 | c.6165T>A p.C2055* | Nonsense Mutation (SNP) | VAF 23/105 reads (22%) | catalogued as COSV65522668; called by muse, mutect2, varscan2
- MEOX1 | c.177C>A p.Y59* | Nonsense Mutation (SNP) | VAF 11/89 reads (12%) | catalogued as COSV59356291; called by muse, mutect2, varscan2
- MOSPD2 | c.332G>T p.R111M | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV66860203; called by muse, mutect2
- MPPED1 | c.186C>A p.N62K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.188); catalogued as COSV61987779; called by muse, mutect2, varscan2
- MRC1 | c.2930G>T p.C977F | Missense Mutation (SNP) | VAF 53/287 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53470304; called by muse, mutect2, varscan2
- MUC16 | c.26308A>G p.I8770V | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.005); catalogued as rs763228724, COSV67470321; called by muse, mutect2, varscan2
- MUC16 | c.12829A>T p.T4277S | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.556); catalogued as COSV67470326; called by muse, mutect2, varscan2
- MYH2 | c.955G>T p.G319W | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55439551; called by muse, mutect2, varscan2
- MYH8 | c.5395C>T p.R1799C | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1204708839, COSV67961549; called by muse, mutect2, varscan2
- MYO10 | c.5287G>T p.D1763Y | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779355146, COSV57022621; called by muse, mutect2, varscan2
- MYO10 | c.3360C>G p.D1120E | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.012); catalogued as COSV57022639; called by muse, mutect2, varscan2
- MYOF | c.6165G>T p.K2055N | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63704975; called by muse, mutect2, varscan2
- MYOF | c.2617A>G p.K873E | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); catalogued as COSV63704987; called by muse, mutect2, varscan2
- NALCN | c.130A>T p.I44F | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV51939229; called by muse, mutect2, varscan2
- NAV3 | c.2154C>A p.D718E | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV57083658; called by muse, mutect2, varscan2
- NCAPD3 | c.2474G>T p.G825V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV73258418; called by muse, mutect2, varscan2
- NLGN4X | c.1321G>T p.V441L | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as COSV52020762; called by muse, mutect2, varscan2
- NLRP10 | c.1386C>A p.Y462* | Nonsense Mutation (SNP) | VAF 25/178 reads (14%) | catalogued as COSV60780555; called by muse, mutect2, varscan2
- NLRP12 | c.2113C>G p.L705V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60748497; called by muse, mutect2, varscan2
- NTF3 | c.599C>A p.P200Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58417682; called by muse, mutect2, varscan2
- NUP210 | c.1340A>T p.E447V | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV54405036, COSV54407158; called by muse, mutect2, varscan2
- NXPE3 | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56290146; called by muse, mutect2, varscan2
- OBSL1 | c.3572T>C p.V1191A | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.855); catalogued as COSV54706629; called by muse, mutect2
- OPRK1 | c.972C>A p.S324R | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV55570561, COSV55571048; called by muse, mutect2, varscan2
- OR1A1 | c.765G>T p.M255I | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV100410709; called by mutect2, varscan2
- OR2B2 | c.536G>C p.C179S | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100308068; called by muse, mutect2, varscan2
- OR2M7 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 83/407 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as COSV58738236, COSV58739311; called by muse, mutect2, varscan2
- OR4A47 | c.440G>T p.W147L | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.673); catalogued as COSV101487052; called by muse, mutect2
- OR4A47 | c.441G>T p.W147C | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.093); catalogued as COSV101487053; called by muse, mutect2
- OR4M1 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.072); catalogued as COSV60061435; called by muse, mutect2, varscan2
- OR51E2 | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV67807660; called by muse, mutect2, varscan2
- OR5L1 | c.685G>T p.G229C | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV61733867, COSV61734113; called by muse, mutect2, varscan2
- PABPC5 | c.219G>C p.E73D | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs769429858, COSV57041192; called by muse, mutect2, varscan2
- PAOX | c.1385G>T p.G462V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.103); catalogued as COSV53372759; called by muse, mutect2
- PAPPA | c.2350G>T p.E784* | Nonsense Mutation (SNP) | VAF 17/92 reads (18%) | catalogued as COSV100073212, COSV60286024; called by muse, mutect2, varscan2
- PARP8 | c.2096C>T p.S699L | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV55860756, COSV55865302; called by muse, mutect2
- PCDH18 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 26/188 reads (14%) | catalogued as COSV61266910, COSV61268874; called by muse, mutect2, varscan2
- PCDHB7 | c.652G>T p.G218C | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782717110, COSV50753777, COSV50773647; called by muse, mutect2, varscan2
- PCOLCE2 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55999457; called by muse, mutect2, varscan2
- PDE6B | c.842C>A p.T281N | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as COSV55327060; called by muse, mutect2, varscan2
- PEAK1 | c.3061G>T p.E1021* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | catalogued as COSV56930084, COSV56936742; called by muse, mutect2, varscan2
- PI16 | c.743T>A p.V248D | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.446); catalogued as COSV65448244; called by muse, mutect2, varscan2
- PI4KA | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV55412529; called by muse, mutect2
- PIKFYVE | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100011061, COSV52242092; called by muse, mutect2, varscan2
- PLCB2 | c.1982T>C p.M661T | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763247618, COSV53034104; called by muse, mutect2, varscan2
- PLCB4 | c.1409A>T p.E470V | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53803768; called by muse, mutect2, varscan2
- PODN | c.833G>T p.R278L (on ENST00000395871; = p.R230L on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as rs1333307112, COSV57012401, COSV57014174; called by muse, mutect2, varscan2
- POM121L12 | c.136C>A p.P46T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV68692644, COSV68693105; called by muse, mutect2, varscan2
- POT1 | c.1393A>T p.K465* | Nonsense Mutation (SNP) | VAF 23/99 reads (23%) | catalogued as rs1246723310, COSV62930763; called by muse, mutect2, varscan2
- PPL | c.2205C>G p.F735L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV62047519; called by muse, mutect2
- PRAMEF6 | c.340A>G p.M114V | Missense Mutation (SNP) | VAF 63/591 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV61910207; called by muse, mutect2, varscan2
- RANBP2 | c.6776G>T p.R2259L | Missense Mutation (SNP) | VAF 93/618 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV51702136; called by muse, mutect2, varscan2
- RCAN3 | c.38A>T p.Q13L | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.953); catalogued as COSV100980323; called by muse, mutect2, varscan2
- RIMBP2 | c.1870G>T p.A624S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV55474367; called by muse, mutect2, varscan2
- RXRG | c.1330G>T p.G444W | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63232246; called by muse, mutect2, varscan2
- RYR2 | c.1916G>T p.G639V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV63688679; called by muse, mutect2, varscan2
- SAGE1 | c.204G>A p.W68* | Nonsense Mutation (SNP) | VAF 66/394 reads (17%) | catalogued as COSV100187440, COSV61014046; called by muse, mutect2, varscan2
- SAMSN1 | c.626A>G p.N209S | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as rs1332466210, COSV53472315; called by muse, mutect2, varscan2
- SCG3 | c.1026G>C p.K342N | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55021528; called by muse, mutect2
- SCN4A | c.5027G>T p.C1676F | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV71127156; called by muse, mutect2, varscan2
- SERPINB13 | c.258C>A p.F86L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV54028861; called by muse, mutect2, varscan2
- SERPINB13 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV99500916; called by muse, mutect2, varscan2
- SERPINB5 | c.632G>A p.S211N | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV66975506; called by muse, mutect2, varscan2
- SF3B1 | c.2695G>T p.A899S | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.486); catalogued as COSV59215494; called by muse, varscan2
- SGCG | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV54561531; called by muse, mutect2, varscan2
- SHOX | c.37G>T p.D13Y | Missense Mutation (SNP) | VAF 34/323 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV61861039; called by muse, varscan2
- SIAH3 | c.119C>A p.P40H | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV68552010; called by muse, mutect2, varscan2
- SIRPA | c.221C>A p.P74Q | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.096); catalogued as COSV61539172; called by muse, mutect2, varscan2
- SLC35G1 | c.960G>T p.M320I (on ENST00000427197 / NM_001134658.3; = p.M319I on NM_153226.4) | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.216); catalogued as COSV101004033; called by muse, mutect2
- SLC5A7 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV50892558; called by muse, mutect2, varscan2
- SMARCA1 | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); catalogued as COSV64412223; called by muse, mutect2, varscan2
- SMG8 | c.612C>G p.F204L | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.21); catalogued as COSV56284092, COSV99958597; called by muse, mutect2, varscan2
- SNAI1 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 24/102 reads (24%) | catalogued as COSV54864166; called by muse, mutect2, varscan2
- SOCS6 | c.982G>T p.G328* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | catalogued as COSV101205679; called by muse, mutect2, varscan2
- STX2 | c.281-2A>T p.X94_splice | Splice Site (SNP) | VAF 55/286 reads (19%) | catalogued as COSV55433931; called by muse, mutect2, varscan2
- SWAP70 | c.1127del p.R376Pfs*52 | Frame Shift Del (DEL) | VAF 14/89 reads (16%) | catalogued as COSV59665566; called by mutect2, pindel, varscan2
- SYN3 | c.622-1G>T p.X208_splice | Splice Site (SNP) | VAF 26/183 reads (14%) | catalogued as COSV56664635; called by muse, mutect2, varscan2
- SYNE2 | c.7395G>C p.L2465F | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV59952952; called by muse, mutect2, varscan2
- SYT13 | c.482A>G p.K161R | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.099); catalogued as COSV50074002; called by muse, mutect2, varscan2
- SYT4 | c.761T>A p.I254N | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54898046; called by muse, mutect2, varscan2
- TAF1A | c.1021G>T p.G341* | Nonsense Mutation (SNP) | VAF 12/74 reads (16%) | catalogued as COSV61918714; called by muse, mutect2, varscan2
- TAFA1 | c.70C>A p.H24N | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV101524389; called by muse, mutect2, varscan2
- TAS2R60 | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); catalogued as COSV100223661, COSV60331060; called by muse, mutect2, varscan2
- TENM1 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 42/278 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV64433361; called by muse, mutect2, varscan2
- TENT5D | c.1085C>A p.P362H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV57636922; called by muse, mutect2, varscan2
- TEX11 | c.1123C>A p.L375M (on ENST00000344304; = p.L360M on NM_031276.3) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV60231750; called by muse, mutect2, varscan2
- TFAP2D | c.788G>C p.R263P | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99145743, COSV99148837; called by muse, mutect2, varscan2
- TM4SF1 | c.319T>A p.C107S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.998); catalogued as COSV59524952; called by muse, mutect2, varscan2
- TNK2 | c.2198dup p.D734* | Frame Shift Ins (INS) | VAF 5/21 reads (24%) | catalogued as rs1197892146; called by mutect2, pindel, varscan2
- TNN | c.2984C>A p.P995H | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs749585837, COSV53427335; called by muse, mutect2
- TNXB | c.7037G>T p.G2346V (on ENST00000647633; = p.G2099V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64480150; called by muse, mutect2, varscan2
- TRIM69 | c.1226C>T p.P409L (on ENST00000329464 / NM_182985.5; = p.P250L on NM_080745.5) | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57803933; called by muse, mutect2
- TRIML2 | c.1136G>C p.G379A | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV58716533; called by muse, mutect2, varscan2
- TSHZ2 | c.1783G>T p.A595S | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV100295559; called by muse, mutect2, varscan2
- UBQLN2 | c.768C>G p.S256R | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV100592644; called by muse, mutect2, varscan2
- USP16 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57625626; called by muse, mutect2, varscan2
- USP26 | c.1296C>A p.C432* | Nonsense Mutation (SNP) | VAF 23/134 reads (17%) | catalogued as COSV100896565; called by muse, mutect2, varscan2
- USP7 | c.2002G>T p.E668* | Nonsense Mutation (SNP) | VAF 11/114 reads (10%) | catalogued as COSV61214993; called by muse, mutect2
- UVSSA | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.114); catalogued as COSV66229999; called by muse, mutect2, varscan2
- WSB1 | c.326T>C p.I109T | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as rs142114425; called by muse, mutect2, varscan2
- XKRX | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 33/186 reads (18%) | catalogued as COSV60708221; called by muse, mutect2, varscan2
- ZBTB2 | c.668A>G p.E223G | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV57312734; called by muse, mutect2, varscan2
- ZNF133 | c.1658G>T p.R553M (on ENST00000316358 / NM_001352454.2; = p.R552M on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.593); catalogued as COSV100315331; called by muse, mutect2, varscan2
- ZNF260 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 33/177 reads (19%) | catalogued as COSV101591036; called by muse, mutect2, varscan2
- ZNF385D | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55756583, COSV55758160; called by muse, mutect2, varscan2
- ZNF397 | c.216G>C p.Q72H | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV99734723; called by muse, mutect2, varscan2
- ZNF546 | c.933T>A p.S311R | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV61258107; called by muse, mutect2, varscan2
- ZNF555 | c.632G>T p.R211L | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.207); catalogued as COSV62073279, COSV62073849; called by muse, mutect2, varscan2
- ZNF800 | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 33/149 reads (22%) | catalogued as COSV56176221; called by muse, mutect2, varscan2
- ATP8B3 | c.1873del p.E625Rfs*10 | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | called by mutect2, pindel, varscan2
- CCL4 | c.252G>T p.E84D | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL11A1 | c.4439del p.G1480Dfs*18 | Frame Shift Del (DEL) | VAF 16/103 reads (16%) | called by mutect2, pindel, varscan2
- FRMD6 | c.721del p.R241Gfs*7 (on ENST00000344768 / NM_001267046.2; = p.R233Gfs*7 on NM_152330.4) | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | called by mutect2, pindel
- GGTLC2 | c.548C>A p.T183N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); called by mutect2, varscan2
- ADGRG2 | c.1389T>A p.T463= (on ENST00000379869 / NM_001079858.3; = p.T460= on NM_005756.4) | Silent (SNP) | VAF 18/134 reads (13%) | catalogued as COSV61339422; called by muse, mutect2, varscan2
- ADGRL2 | c.2325G>T p.L775= (on ENST00000370717 / NM_001366005.1; = p.L762= on NM_012302.4) | Silent (SNP) | VAF 24/182 reads (13%) | catalogued as COSV54669918; called by muse, mutect2, varscan2
- AGAP1 | c.789G>T p.V263= | Silent (SNP) | VAF 47/267 reads (18%) | catalogued as COSV58327573; called by muse, mutect2, varscan2
- AKAP12 | c.3684G>C p.V1228= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV53575998; called by muse, mutect2, varscan2
- AP1B1 | c.1560G>T p.R520= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV58018326; called by muse, mutect2, varscan2
- ARMC5 | c.1692A>T p.P564= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as rs1318888007, COSV51656977; called by muse, mutect2
- ATXN3L | c.1008C>A p.A336= | Silent (SNP) | VAF 72/304 reads (24%) | catalogued as COSV66075212, COSV66075766; called by muse, mutect2, varscan2
- BLK | c.900C>T p.Y300= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs139994406; called by muse, mutect2, varscan2
- BSN | c.7485G>A p.L2495= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV56519414; called by muse, mutect2, varscan2
- C1orf87 | c.538C>T p.L180= | Silent (SNP) | VAF 41/178 reads (23%) | catalogued as rs752693185, COSV64597295; called by muse, mutect2, varscan2
- CCDC33 | c.987C>T p.G329= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV100350826; called by muse, mutect2, varscan2
- CDH18 | c.1419A>T p.T473= | Silent (SNP) | VAF 53/156 reads (34%) | catalogued as COSV56926546; called by muse, mutect2, varscan2
- CEP44 | c.1020A>C p.T340= | Silent (SNP) | VAF 32/196 reads (16%) | catalogued as COSV56659507; called by muse, mutect2, varscan2
- CHST4 | c.295C>A p.R99= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV58297392; called by muse, mutect2, varscan2
- CNGA4 | c.225G>T p.T75= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV66006128; called by muse, mutect2, varscan2
- CNMD | c.510T>A p.L170= | Silent (SNP) | VAF 32/130 reads (25%) | catalogued as COSV65032870, COSV65033137; called by muse, mutect2, varscan2
- DHRS4 | c.600G>C p.L200= | Silent (SNP) | VAF 16/226 reads (7%) | catalogued as rs761354366, COSV57480996; called by muse, mutect2
- EPHA8 | c.1467C>A p.T489= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV51271270, COSV51300813; called by muse, mutect2, varscan2
- FAM193A | c.723A>T p.P241= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as COSV61194666; called by muse, mutect2, varscan2
- FAM47A | c.1882C>T p.L628= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV60497215; called by muse, mutect2, varscan2
- FGB | c.1188C>A p.T396= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as COSV57418616; called by muse, mutect2, varscan2
- FGD1 | c.420G>T p.P140= | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as COSV64308414, COSV64308834; called by muse, mutect2, varscan2
- FOCAD | c.3654G>T p.L1218= | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as COSV58100294; called by muse, mutect2, varscan2
- GLP1R | c.1068C>A p.L356= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as COSV64715231; called by muse, mutect2, varscan2
- GPR142 | c.1053G>T p.R351= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV59519396; called by muse, mutect2, varscan2
- GPR50 | c.1563C>A p.P521= | Silent (SNP) | VAF 38/162 reads (23%) | catalogued as COSV54439459; called by muse, mutect2, varscan2
- GRIN2A | c.963C>T p.Y321= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs368200727; ClinVar: likely benign; called by muse, mutect2, varscan2
- HACD3 | c.138A>T p.G46= | Silent (SNP) | VAF 28/246 reads (11%) | catalogued as COSV99970939; called by muse, mutect2, varscan2
- HSPB7 | c.465G>T p.P155= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV61308111; called by muse, mutect2, varscan2
- HYDIN | c.6654G>A p.L2218= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99992244; called by muse, mutect2, varscan2
- IP6K3 | c.870T>C p.N290= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as rs1328309302, COSV53390417; called by muse, mutect2, varscan2
- KIF2B | c.618G>T p.L206= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV52131152; called by muse, mutect2, varscan2
- LCE2C | c.252C>A p.R84= | Silent (SNP) | VAF 29/134 reads (22%) | catalogued as rs769887881, COSV100909403; called by muse, mutect2, varscan2
- LRRC66 | c.2457G>T p.P819= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV58634251; called by mutect2, varscan2
- MCM8 | c.1452C>T p.T484= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs113442872; called by muse, mutect2, varscan2
- MFF | c.435A>T p.R145= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV58825763; called by muse, mutect2, varscan2
- NAV2 | c.225G>T p.P75= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV62324318; called by muse, mutect2, varscan2
- OMG | c.768C>A p.T256= | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as COSV99907832; called by muse, mutect2, varscan2
- OR1F1 | c.828G>T p.V276= | Silent (SNP) | VAF 30/208 reads (14%) | catalogued as COSV58961203; called by muse, mutect2, varscan2
- OR2M7 | c.924C>A p.G308= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs1252958279, COSV58739289; called by muse, varscan2
- PATJ | c.5388G>T p.L1796= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV64504011; called by muse, mutect2, varscan2
- PC | c.1344G>T p.A448= | Silent (SNP) | VAF 35/225 reads (16%) | catalogued as COSV58921802; called by muse, mutect2, varscan2
- PCNT | c.2220G>A p.L740= | Silent (SNP) | VAF 38/182 reads (21%) | catalogued as COSV64028969; called by muse, mutect2, varscan2
- PDK4 | c.930A>G p.T310= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as rs148379762; called by muse, mutect2, varscan2
- PLCB4 | c.3012G>C p.T1004= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV53803791; called by muse, mutect2, varscan2
- PLXNA3 | c.2712C>A p.P904= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as COSV63754315; called by muse, mutect2, varscan2
- PTPRN2 | c.588G>T p.V196= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV67040464; called by muse, mutect2, varscan2
- RAB3GAP2 | c.126A>G p.T42= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as COSV52965970; called by muse, mutect2, varscan2
- RPL10L | c.87C>A p.A29= | Silent (SNP) | VAF 18/174 reads (10%) | catalogued as COSV100022442; called by muse, mutect2, varscan2
- RTEL1 | c.147G>C p.T49= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV58895025; called by muse, mutect2, varscan2
- SCG2 | c.1026T>A p.P342= | Silent (SNP) | VAF 19/182 reads (10%) | catalogued as COSV59540395; called by muse, mutect2, varscan2
- SF3B3 | c.2598C>T p.I866= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV56786401; called by muse, mutect2, varscan2
- SLC17A4 | c.951G>C p.T317= | Silent (SNP) | VAF 49/118 reads (42%) | catalogued as COSV64956402; called by muse, mutect2, varscan2
- SLC35A2 | c.1113G>T p.P371= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV99504111, COSV99504273; called by muse, mutect2, varscan2
- TEKT1 | c.1114C>T p.L372= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as COSV58623356; called by muse, mutect2, varscan2
- TFAP2D | c.789C>A p.R263= | Silent (SNP) | VAF 26/182 reads (14%) | catalogued as COSV99145745; called by muse, mutect2, varscan2
- TMTC1 | c.2277C>A p.A759= (on ENST00000539277 / NM_001193451.2; = p.A651= on NM_175861.3) | Silent (SNP) | VAF 28/161 reads (17%) | catalogued as COSV55483260; called by muse, mutect2, varscan2
- TNIK | c.1275G>T p.R425= | Silent (SNP) | VAF 45/251 reads (18%) | catalogued as COSV52683917; called by muse, mutect2, varscan2
- TRABD2A | c.1161G>A p.P387= (on ENST00000409520 / NM_001277053.2; = p.P338= on NM_001080824.3) | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs375900394, COSV52886894, COSV99403987; called by muse, mutect2, varscan2
- TRPC5 | c.120G>T p.V40= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV53291998; called by muse, mutect2, varscan2
- TSHZ2 | c.1782G>A p.L594= | Silent (SNP) | VAF 30/193 reads (16%) | catalogued as rs1338257135, COSV100295552; called by muse, mutect2, varscan2
- TSR2 | c.39G>T p.R13= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1569540721, COSV64308830; called by muse, mutect2
- UBN1 | c.745C>T p.L249= | Silent (SNP) | VAF 38/215 reads (18%) | catalogued as COSV52168633; called by muse, mutect2, varscan2
- UNC45B | c.2541C>A p.T847= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as rs201746299, COSV52097341; called by muse, mutect2, varscan2
- USP51 | c.2067C>T p.T689= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV101540676, COSV72351700; called by muse, mutect2, varscan2
- WNT5A | c.831G>T p.R277= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99224776; called by muse, mutect2
- WSB1 | c.561G>T p.V187= | Silent (SNP) | VAF 30/153 reads (20%) | catalogued as COSV99285933; called by muse, mutect2, varscan2
- YTHDC1 | c.1287G>T p.V429= (on ENST00000344157 / NM_001031732.4; = p.V411= on NM_133370.4) | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as COSV60010674; called by muse, mutect2, varscan2
- ZBTB33 | c.180C>A p.L60= | Silent (SNP) | VAF 60/390 reads (15%) | catalogued as COSV100434093; called by muse, mutect2, varscan2
- ZFC3H1 | c.408G>T p.R136= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as COSV57348768; called by muse, mutect2, varscan2
- ZFP36 | c.534G>A p.L178= (on ENST00000594442; = p.L172= on NM_003407.5) | Silent (SNP) | VAF 28/165 reads (17%) | catalogued as COSV50528536; called by muse, mutect2, varscan2
- BIRC8 | n.1207A>T | RNA (SNP) | VAF 20/100 reads (20%) | catalogued as COSV70347000; called by muse, mutect2, varscan2
- CTAG2 | c.*134C>T | 3'UTR (SNP) | VAF 12/80 reads (15%) | catalogued as rs1236503519, COSV55994324; called by muse, mutect2, varscan2
- FBLN1 | c.1698-11306_1698-11305del | Intron (DEL) | VAF 10/109 reads (9%) | called by mutect2, varscan2
- GBA3 | c.59-8199C>A | Intron (SNP) | VAF 52/278 reads (19%) | called by muse, mutect2, varscan2
- H2BP2 | chr1:143876281 C>A | 3'Flank (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- NEB | c.8890-341G>T | Intron (SNP) | VAF 58/375 reads (15%) | catalogued as COSV99417065; called by muse, mutect2, varscan2
- PTPRK | c.578-1127G>T | Intron (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- WASF4P | n.658G>T | RNA (SNP) | VAF 14/133 reads (11%) | called by muse, mutect2, varscan2
- WDR92 | chr2:68125339 C>A | 3'Flank (SNP) | VAF 27/201 reads (13%) | called by muse, mutect2, varscan2
- XIST | n.7997A>G | RNA (SNP) | VAF 19/123 reads (15%) | catalogued as rs1439459600; called by muse, mutect2, varscan2
